Gene-level copy-number profile of tumor specimen TCGA-CN-4740-01A from TCGA case TCGA-CN-4740, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 79.9 years (29,186 days).
Specimen TCGA-CN-4740-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.94b489d3-4bb0-4ec1-85c3-42ade4a54c73.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-4740-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6a265df6-0159-43f3-95b9-e94e629bcbb0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 953; copy number 2: 10,942; copy number 3: 29,360; copy number 4: 3,751; copy number 5: 12,532; copy number 6: 214; copy number 7: 1,218; copy number 8: 1; copy number 9: 518; copy number 10: 11; copy number 12: 5; copy number 13: 16; copy number 14: 181; copy number 16: 5; copy number 20: 17; copy number 21: 7; copy number 24: 50; copy number 25: 2; copy number 28: 28; copy number 40: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-4740-01A-01D-1432-01): tumor purity 0.24, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,936,079–9,803,784, 4 genes: AL596451.1, RPS26P3, RN7SL5P, AL513422.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,064 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,026,895–46,207,386, 164 genes, copy number 8–14 (broad region; genes not listed).
- chr6:58,386,799–62,461,503, 13 genes, copy number 7–10: AL603755.1, AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5.
- chr6:63,211,446–63,779,336, 15 genes, copy number 14: FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 14: AL354719.1, SCAT8, GCNT1P4.
- chr6:70,394,881–74,850,484, 78 genes, copy number 7 (broad region; genes not listed).
- chr7:91,692,008–93,911,265, 41 genes, copy number 7–28 (within-gene range 3–28): MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2.
- chr8:35,672,195–145,066,685, 1,723 genes, copy number 7–25 (broad region; genes not listed).
- chr13:71,437,966–73,661,891, 27 genes, copy number 12–40 (within-gene range 1–40): DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.

Autosomal genes at a single copy (total copy number 1): 953. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
